Somatic mutation profile of tumor specimen TCGA-29-1783-01A (aliquot TCGA-29-1783-01A-01W-0633-09) from TCGA case TCGA-29-1783, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.3 years (21,284 days).
Specimen TCGA-29-1783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e740dde-e0fc-404b-ab20-a7cf36995c26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1783-10A (Blood Derived Normal), aliquot TCGA-29-1783-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d8578ce-aa27-421c-bf12-e72c34cadae9

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Frame Shift Ins 3, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNC | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs755583250, COSV57950044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4718G>A p.G1573E | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV64674500; called by muse, mutect2, varscan2
- ACTBL2 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV70661401; called by muse, mutect2, varscan2
- AHNAK | c.9118C>T p.P3040S | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV99946738; called by muse, mutect2, varscan2
- AP1M2 | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51567796; called by muse, mutect2, varscan2
- ASAH2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 84/395 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs777210243, COSV61483878; called by muse, mutect2, varscan2
- ATP5F1A | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); catalogued as COSV56360761; called by muse, mutect2, varscan2
- ATP7A | c.3431A>T p.N1144I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as CD154619, COSV100430575; called by muse, mutect2
- BRIP1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52001468; called by muse, mutect2, varscan2
- CA10 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.982); catalogued as COSV53355529; called by muse, mutect2, varscan2
- CLCN5 | c.1582C>A p.L528M | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56584926; called by muse, mutect2, varscan2
- CPT2 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.791); catalogued as COSV53759575; called by muse, mutect2, varscan2
- CSMD3 | c.9707C>T p.P3236L (on ENST00000297405 / NM_001363185.1; = p.P3067L on NM_052900.3) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99822943, COSV99830512; called by muse, mutect2
- CSRNP2 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57334542; called by muse, mutect2, varscan2
- CTDSP2 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV66079984; called by muse, mutect2, varscan2
- DOCK11 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV52241384; called by muse, mutect2, varscan2
- DYNC1H1 | c.8851G>A p.A2951T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64138205; called by muse, mutect2, varscan2
- ESF1 | c.2227A>T p.M743L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52521833; called by muse, mutect2, varscan2
- GIGYF2 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV104424019, COSV65250617; called by muse, mutect2, varscan2
- GPR34 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59364395; called by muse, mutect2, varscan2
- GRM1 | c.1105C>G p.P369A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV51121146, COSV51175424; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2, varscan2
- HNF1B | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1293305953; called by muse, mutect2, varscan2
- KCND3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1198744961, COSV56181694; called by muse, mutect2, varscan2
- LPAR4 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.131); catalogued as COSV70912826; called by muse, mutect2, varscan2
- MAGEB6 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV66872470; called by muse, mutect2, varscan2
- MAGI3 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as COSV100288604; called by muse, mutect2
- MCOLN2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99393740; called by muse, mutect2
- MYO1A | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145245907; called by muse, mutect2, varscan2
- OR13H1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV58547848; called by muse, mutect2, varscan2
- OR14C36 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507483; called by muse, mutect2, varscan2
- PKHD1L1 | c.7835T>A p.F2612Y | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65745635; called by muse, mutect2, varscan2
- PPFIA2 | c.2461C>G p.L821V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100332660; called by muse, mutect2, varscan2
- PPP1R15A | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 130/386 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV52339353; called by muse, mutect2, varscan2
- PPP1R15A | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 172/548 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339362; called by muse, varscan2
- PPP1R15A | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 146/438 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778736029, COSV52339369; called by muse, varscan2
- PPP1R15A | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52339375; called by muse, mutect2, varscan2
- PPP1R15A | c.1705G>C p.V569L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52339385; called by muse, mutect2, varscan2
- RAPGEF2 | c.2668G>A p.G890R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs377126972; called by muse, mutect2, varscan2
- RAPH1 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100051337; called by muse, mutect2
- RNF148 | c.784T>A p.F262I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV57368705; called by muse, mutect2, varscan2
- ROCK2 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55080457; called by muse, mutect2, varscan2
- RPS6KA1 | c.2137dup p.Q713Pfs*36 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | catalogued as rs750092723; called by pindel, varscan2
- SCNN1G | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.163); catalogued as COSV100264081; called by muse, mutect2
- SPIN3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66529103, COSV66529289; called by muse, mutect2, varscan2
- TMPRSS11A | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs370242991, COSV58359219; called by muse, mutect2, varscan2
- TP53 | c.366_367dup p.T123Rfs*48 | Frame Shift Ins (INS) | VAF 73/108 reads (68%) | catalogued as COSV99480049; called by mutect2, pindel, varscan2
- ZFAND1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as rs1173671877, COSV55106673; called by muse, mutect2
- ZFYVE1 | c.1343A>T p.K448M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100606672; called by muse, mutect2, varscan2
- ZNF302 | c.1006T>G p.Y336D (on ENST00000627982; = p.Y257D on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101416461; called by muse, mutect2
- ZSWIM8 | c.3766A>T p.S1256C (on ENST00000605216 / NM_001242487.2; = p.S1261C on NM_015037.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55215634; called by muse, mutect2, varscan2
- DGKK | c.3323_3326dup p.N1110Cfs*6 | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- LRRC40 | c.792T>A p.C264* | Nonsense Mutation (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- TBL1XR1 | c.606_624del p.T203* | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- ACSBG1 | c.1656C>T p.G552= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV51907361; called by muse, mutect2, varscan2
- ATRNL1 | c.1866A>G p.E622= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61807145; called by muse, mutect2, varscan2
- BRWD3 | c.1986A>T p.L662= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100955887; called by muse, mutect2
- CYP3A4 | c.822G>C p.L274= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1295069475, COSV100315570, COSV100315690; called by muse, mutect2
- DHX34 | c.1740A>G p.L580= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs754715456, COSV60894644; called by muse, mutect2
- GSN | c.582G>A p.G194= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs758568228, COSV57998488; called by muse, mutect2, varscan2
- KRT73 | c.165G>C p.R55= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV59839851; called by muse, mutect2, varscan2
- PPP1R15A | c.180G>A p.L60= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs777037170, COSV99565940; called by muse, mutect2, varscan2
- REXO5 | c.228C>G p.G76= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV54472799; called by muse, mutect2, varscan2
- RFTN2 | c.108C>T p.Y36= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs762039291, COSV54386699; called by muse, mutect2, varscan2
- RPS6KA2 | c.1773G>A p.A591= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs55690286; called by muse, mutect2, varscan2
- SPOCK1 | c.1314A>T p.I438= | Silent (SNP) | VAF 8/157 reads (5%) | catalogued as COSV99968534; called by muse, mutect2
- TRO | c.1569A>C p.I523= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV51503021; called by muse, mutect2, varscan2
- ZFAND4 | c.651T>C p.N217= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV60859604; called by muse, mutect2, varscan2
- EIF4A1 | c.514+143T>G | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as COSV51511204; called by muse, mutect2, varscan2
- MROH8 | c.109+2751G>C | Intron (SNP) | VAF 34/235 reads (14%) | catalogued as COSV54121130; called by muse, mutect2, varscan2
- SDK1 | c.*3306C>T | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as rs746750629, COSV67374433; called by muse, mutect2
